Somatic mutation profile of tumor specimen TCGA-OR-A5J6-01A (aliquot TCGA-OR-A5J6-01A-31D-A29I-10) from TCGA case TCGA-OR-A5J6, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 29.7 years (10,839 days).
Specimen TCGA-OR-A5J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cc0204f-9bc6-4e86-9bbc-e417c9fc89b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5J6-10A (Blood Derived Normal), aliquot TCGA-OR-A5J6-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d86c6b7f-9874-4ed1-83f2-429a515a9586

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.620C>T p.S207F | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1200747310; called by muse, mutect2, varscan2
- ANAPC10 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748838277; called by muse, mutect2, varscan2
- ASPH | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs768498732, COSV62859837; called by muse, mutect2, varscan2
- BCAT1 | c.884T>C p.L295P | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53907753; called by muse, mutect2, varscan2
- CDKL5 | c.2269G>T p.D757Y | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV66113142; called by muse, mutect2, varscan2
- G6PC3 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200478425, CM090105; called by muse, mutect2, varscan2
- H1-4 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV99060555; called by muse, mutect2, varscan2
- IGF2R | c.1015A>G p.I339V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs369933452; called by muse, mutect2, varscan2
- MUC13 | c.1270A>G p.T424A | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs767473624; called by muse, mutect2, varscan2
- SH3RF3 | c.1754C>G p.S585W | Missense Mutation (SNP) | VAF 49/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58685299, COSV58686774; called by muse, mutect2, varscan2
- SNTG1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 5/128 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99035425; called by muse, mutect2
- ADAMTS19 | c.1271T>A p.M424K | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- CAPZA2 | c.721-2A>G p.X241_splice | Splice Site (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- CFAP77 | c.920T>C p.V307A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CNBD1 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- CRACR2A | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- GLRA1 | c.743T>A p.M248K | Missense Mutation (SNP) | VAF 56/245 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- LRRN3 | c.1480T>C p.Y494H | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAP1L1 | c.815C>G p.T272S | Missense Mutation (SNP) | VAF 11/188 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2
- OTP | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 41/197 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- POLR1C | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TMEM177 | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF813 | c.1484A>G p.Y495C | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- ADAMTS3 | c.642C>G p.S214= | Silent (SNP) | VAF 15/87 reads (17%) | called by muse, mutect2, varscan2
- GTSF1 | c.465G>T p.P155= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as COSV59938626; called by muse, mutect2, varscan2
- MEGF8 | c.1497G>A p.P499= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs374205876; called by muse, mutect2, varscan2
- OMA1 | c.90A>G p.T30= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs772496911; called by mutect2, varscan2
- PCDH15 | c.5205C>T p.A1735= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100219976, COSV57403348; called by muse, mutect2, varscan2
- PKD1L2 | c.1405T>C p.L469= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as rs760152082; called by muse, mutect2, varscan2
- SH3KBP1 | c.1362C>T p.L454= | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- FRY | c.71-17717T>C | Intron (SNP) | VAF 33/172 reads (19%) | called by muse, mutect2, varscan2
